Gene-level copy-number profile of tumor specimen ALCH-B3AU-TTR1-A from ALCHEMIST case ALCH-B3AU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (18,980 days).
Specimen ALCH-B3AU-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6b256b2-e7f9-4448-ba44-6deaf54ac560.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/092c8cc5-01fc-46b4-aee9-808cf9b33f61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 15,425; copy number 2: 37,496; copy number 3: 4,826; copy number 4: 448; copy number 5: 32; copy number 6: 1; copy number 7: 56; copy number 10: 49; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,100,305–9,196,284, 2 genes: GPR157, LNCTAM34A.
- chr1:9,539,465–9,614,877, 3 genes: SLC25A33, AL954705.1, TMEM201.
- chr1:10,163,268–10,163,374, 1 gene (within-gene range 0–1): RNU6-828P.
- chr1:41,014,590–41,043,890, 2 genes (within-gene range 0–2): SLFNL1-AS1, SLFNL1.
- chr3:147,386,046–147,406,809, 2 genes (within-gene range 0–2): ZIC4, ZIC4-AS1.
- chr8:127,794,526–128,187,101, 8 genes (within-gene range 0–1): PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1.
- chr8:128,049,152–128,049,238, 1 gene (within-gene range 0–1): MIR1207.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:25,180,497–25,206,343, 15 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20.
- chr15:25,230,838–25,238,067, 5 genes (within-gene range 0–1): SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr15:25,250,859–25,250,940, 1 gene (within-gene range 0–1): SNORD115-44.
- chr17:41,609,778–41,640,199, 3 genes: KRT16, KRT17, KRT42P.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr18:23,134,564–23,260,467, 1 gene (within-gene range 0–1): CABLES1.
- chr22:50,691,260–50,691,363, 1 gene (within-gene range 0–2): RNU6-409P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 139 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,790,442–15,859,771, 91 genes, copy number 7–10 (broad region; genes not listed).
- chr7:94,782,886–94,834,447, 3 genes, copy number 5: GRPEL2P3, RN7SKP129, ARF1P1.
- chr11:1,157,953–1,201,138, 1 gene, copy number 5: MUC5AC.
- chr14:105,583,731–105,669,843, 8 genes, copy number 5 (within-gene range 2–5): IGHA2, IGHE, IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP.
- chr19:1,228,287–1,239,522, 2 genes, copy number 5–7 (within-gene range 2–7): CBARP, AC004221.1.
- chr19:32,687,089–32,829,580, 4 genes, copy number 5 (within-gene range 3–5): AC008736.1, NUDT19, AC008736.2, TDRD12.
- chr19:40,924,219–41,027,720, 4 genes, copy number 5: CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1.
- chr19:41,521,043–41,881,372, 25 genes, copy number 5–7: PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A.
- chr22:50,669,804–50,669,901, 1 gene, copy number 14: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 13,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
